CPTAC case C3L-04011 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9afd0b34-4442-4578-9f21-922becc147b3

Demographics
Sex at birth: female; Race: white; Year of birth: 1960; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 58.3 years (21,276 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: MX; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 465 days (1.3 years); Days to last follow up: 465 days (1.3 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 1 cm; Lymph node involvement: Positive; Lymph nodes positive: 5; Lymph nodes tested: 15; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 417 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 465 days (1.3 years); Disease response: With Tumor.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04011-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 379 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04011-24: Section location: Lymph node; Percent tumor nuclei: 90; Percent necrosis: 0.
- Sample C3L-04011-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
